Gene-level copy-number profile of specimen HCM-CSHL-0852-C76-85A from HCMI case HCM-CSHL-0852-C76, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; Tumor grade: GX.
Specimen HCM-CSHL-0852-C76-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a6e0d239-a82c-47fe-9a23-973034b48176.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0852-C76-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/54f64cbe-c231-4338-b035-dd6392f49d76

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 20,462; copy number 2: 34,455; copy number 3: 3,078; copy number 4: 758; copy number 5: 65; copy number 6: 1; copy number 7: 1; copy number 9: 14; copy number 13: 7; copy number 15: 5; copy number 17: 9; copy number 18: 3; copy number 22: 5; copy number 23: 3; copy number 25: 2; copy number 26: 1; copy number 30: 18; copy number 34: 5; copy number 38: 8; copy number 40: 2; copy number 43: 3; copy number 44: 7.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 159 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:187,370,648–190,092,279, 56 genes, copy number 5: LINC02514, LINC02515, AC093763.2, AC093763.1, LINC02492, AC097521.1, ADAM20P3, AC108073.1, ZFP42, TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434, AC093789.1, ICE2P1, LINC01060, AC093909.3, AC093909.5, RNU7-192P, AC093909.1, AC093909.6, AC093909.2, LINC02508, AC093909.4, AC122138.1, AC107391.1, AC105924.1, HSP90AA4P, LINC01262, AF250324.1, RNU1-51P, FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr7:102,637,049–102,671,641, 3 genes, copy number 5 (within-gene range 1–5): AC105052.3, SPDYE2B, POLR2J2.
- chr8:105,826,570–105,834,038, 1 gene, copy number 6 (within-gene range 6–10): AC090802.1.
- chr8:111,621,458–113,436,939, 6 genes, copy number 5–7 (within-gene range 2–7): H2AZP7, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053.
- chr8:113,432,224–113,433,129, 1 gene, copy number 5: AC055788.2.
- chr11:69,641,156–70,436,584, 27 genes, copy number 9–34: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:100,641,975–104,164,379, 65 genes, copy number 13–44 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 18,421. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
